Somatic mutation profile of tumor specimen TCGA-A4-8312-01A (aliquot TCGA-A4-8312-01A-11D-2396-08) from TCGA case TCGA-A4-8312, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.9 years (22,231 days).
Specimen TCGA-A4-8312-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7631a7e-adad-49f6-831a-2e1bdc75e991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8312-10A (Blood Derived Normal), aliquot TCGA-A4-8312-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d38bcd4-63e5-4c60-933e-2712f20dec0d

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 17/34 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMBP | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs142189555; called by muse, mutect2, varscan2
- ATP10A | c.847+2T>A p.X283_splice | Splice Site (SNP) | VAF 32/76 reads (42%) | catalogued as COSV63516269; called by muse, mutect2, varscan2
- MMP13 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV52823656; called by muse, mutect2
- MTUS2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1443904265, COSV70912573; called by muse, mutect2, varscan2
- PPIL1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63836884; called by muse, mutect2
- STYXL2 | c.2717A>C p.K906T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs377480316; called by mutect2, varscan2
- TRIP11 | c.3666A>T p.E1222D | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50917650; called by muse, mutect2, varscan2
- BICD1 | c.2574_2575del p.Q858Hfs*7 | Frame Shift Del (DEL) | VAF 55/189 reads (29%) | called by mutect2, pindel, varscan2
- GRIN2D | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LYZL6 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FBXW2 | c.1149C>T p.D383= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs1350286153, COSV61596791; called by muse, mutect2
- MYCBPAP | c.1371A>T p.R457= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as COSV60406864; called by muse, mutect2, varscan2
- SLC8A3 | c.1863G>A p.P621= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs376675749; called by muse, mutect2, varscan2
- SMARCAL1 | c.375C>G p.P125= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV100619698, COSV61920725; called by muse, mutect2, varscan2
- SRCAP | c.327G>T p.R109= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV52671132; called by muse, mutect2, varscan2
